OHSU case 1236 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e1b26c34-02cd-4352-ad99-51072b1ebf41

Demographics
Sex at birth: female; Vital status: Dead.

Diagnoses (1)
1. Myloproliferative neoplasm, unclassifiable: ICD-O-3 morphology code: 9975/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.0 years (17,166 days); Days to last follow up: 649 days (1.8 years).

Biospecimens (1 sample)
- Sample 3472D: Tissue type: Tumor; Preservation method: Snap Frozen.
